Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5L4, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5L4-01A (Primary Tumor).

Procedure: adrenalectomy and resection of tumor in vena cava, choecystectomy

Gross description: 15 x 9 x 7cm primary tumor, 13.5 x 5.5 x 5cm tumor in vena cava

Diagnosis: adrenocortical carcinoma, KI67 10%, pT2 pNx L0 V1 Pn0 R0

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 10-20%

Weiss score: 7

Hough score: 3.29

Van Slooten score: 13.7

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site Adrenal Gland, Cortex
C74.0

MD 2/6/13

Criteria	hw 1/14/13	Yes	No

Source: NCI Genomic Data Commons file 1cdfff5a-81f3-4043-a002-0d6835a8a2a4 (TCGA-OR-A5L4.B140F5B4-5B03-40EC-A5BB-BCF0963EC567.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).